Somatic mutation profile of tumor specimen MMRF_1389_1_BM_CD138pos (aliquot MMRF_1389_1_BM_CD138pos_T1_KAS5U_L00658) from MMRF case MMRF_1389, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 51.9 years (18,960 days).
Specimen MMRF_1389_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0e0be069-5baf-4efd-881e-707baf754d8f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1389_2_PB_WBC (Blood Derived Normal), aliquot MMRF_1389_2_PB_WBC_C2_KBS5U_L05826; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5b8310b2-4f9d-4d38-ad05-a946c25b843c

The open-access MAF lists 516 somatic variants for this specimen: 193 protein-altering or splice-affecting, 72 silent, 251 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 168, 3'UTR 139, Silent 72, Intron 50, 5'UTR 26, 5'Flank 16, Nonsense Mutation 12, 3'Flank 11, RNA 9, Splice Region 6, Splice Site 5, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DIS3 | c.2339G>C p.R780T | Missense Mutation (SNP) | VAF 53/103 reads (51%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66705570, COSV66707409; called by muse, mutect2, varscan2
- ABRAXAS2 | c.971G>T p.R324L | Missense Mutation (SNP) | VAF 28/75 reads (37%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as rs546644115, COSV53716857; called by muse, mutect2, varscan2
- ACVRL1 | c.247G>A p.E83K | Missense Mutation (SNP) | VAF 22/26 reads (85%) | SIFT tolerated (0.79); PolyPhen benign (0.009); catalogued as rs200960874; called by muse, mutect2, varscan2
- ADAMTS14 | c.2309G>T p.G770V | Missense Mutation (SNP) | VAF 25/64 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.758); catalogued as rs760708709; called by muse, mutect2, varscan2
- ADRB3 | c.649C>T p.L217F | Missense Mutation (SNP) | VAF 8/88 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1202181418; called by muse, mutect2
- ANKRD30B | c.1609G>A p.E537K | Missense Mutation (SNP) | VAF 11/80 reads (14%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV100745809; called by muse, mutect2, varscan2
- ANPEP | c.2115C>A p.F705L | Missense Mutation (SNP) | VAF 14/93 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.511); catalogued as COSV55591406; called by muse, mutect2, varscan2
- BIRC3 | c.1664G>C p.R555T | Missense Mutation (SNP) | VAF 36/36 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54816068; called by muse, mutect2, varscan2
- BTK | c.1932C>G p.F644L | Missense Mutation (SNP) | VAF 24/109 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as CD984187, CM973353; called by muse, mutect2, varscan2
- CAVIN1 | c.715G>A p.E239K | Missense Mutation (SNP) | VAF 50/102 reads (49%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.54); catalogued as rs752731739; called by muse, mutect2, varscan2
- CCDC7 | c.796+1G>A p.X266_splice | Splice Site (SNP) | VAF 27/41 reads (66%) | catalogued as rs150437631; called by muse, mutect2, varscan2
- CFAP20DC | c.1066G>C p.D356H (on ENST00000482387 / NM_001351530.2; = p.D231H on NM_198463.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 9/77 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1220957128; called by muse, mutect2, varscan2
- CPPED1 | c.889G>C p.E297Q | Missense Mutation (SNP) | VAF 58/232 reads (25%) | SIFT tolerated (0.4); PolyPhen benign (0.03); catalogued as rs1323563878; called by muse, mutect2, varscan2
- CRISPLD2 | c.1303G>A p.D435N | Missense Mutation (SNP) | VAF 69/136 reads (51%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.955); catalogued as rs765014952; called by muse, mutect2, varscan2
- CTNNA3 | c.284G>A p.R95H | Missense Mutation (SNP) | VAF 13/89 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.603); catalogued as rs779423519, COSV57717865, COSV57720911; called by muse, mutect2, varscan2
- DEPTOR | c.665G>A p.R222Q | Missense Mutation (SNP) | VAF 48/82 reads (59%) | SIFT tolerated (0.13); PolyPhen benign (0.23); catalogued as rs759755175, COSV53815248; called by muse, mutect2, varscan2
- DYNC2LI1 | c.946C>T p.Q316* | Nonsense Mutation (SNP) | VAF 10/93 reads (11%) | catalogued as COSV53185832; called by muse, mutect2, varscan2
- EDN2 | c.112C>G p.H38D | Missense Mutation (SNP) | VAF 13/26 reads (50%) | SIFT tolerated (0.25); PolyPhen benign (0.015); catalogued as COSV65423424; called by muse, mutect2, varscan2
- EPHB3 | c.1746C>T p.L582= | Splice Region (SNP) | VAF 31/59 reads (53%) | catalogued as COSV57803945; called by muse, mutect2, varscan2
- ERG | c.1057G>C p.E353Q (on ENST00000398919 / NM_001243428.1; = p.E329Q on NM_004449.4) | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV55731628; called by muse, mutect2
- EYA2 | c.921G>A p.M307I | Missense Mutation (SNP) | VAF 42/94 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.207); catalogued as COSV57941081; called by muse, mutect2, varscan2
- F7 | c.635G>A p.R212Q | Missense Mutation (SNP) | VAF 5/116 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs868044209, CM034800, CM940390; called by muse, mutect2
- FAM200B | c.550G>C p.D184H | Missense Mutation (SNP) | VAF 7/57 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.892); catalogued as COSV69959721; called by muse, mutect2, varscan2
- FAXC | c.936C>G p.I312M | Missense Mutation (SNP) | VAF 17/33 reads (52%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.952); catalogued as COSV67601843; called by muse, mutect2, varscan2
- FLNA | c.6844G>A p.E2282K (on ENST00000369850 / NM_001110556.2; = p.E2274K on NM_001456.3) | Missense Mutation (SNP) | VAF 21/79 reads (27%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.575); catalogued as COSV61037284; called by muse, mutect2, varscan2
- FOXR2 | c.791G>A p.R264K | Missense Mutation (SNP) | VAF 4/90 reads (4%) | SIFT tolerated (0.46); PolyPhen benign (0.078); catalogued as COSV59259779; called by muse, mutect2
- GIMAP2 | c.349C>T p.R117C | Missense Mutation (SNP) | VAF 40/61 reads (66%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs562177098, COSV56235922, COSV56236152; called by muse, mutect2, varscan2
- GRIN3A | c.2189G>A p.R730K | Missense Mutation (SNP) | VAF 42/84 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as COSV100701418; called by muse, mutect2, varscan2
- IGHV2-70 | c.170G>C p.W57S | Missense Mutation (SNP) | VAF 48/71 reads (68%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); catalogued as rs374376585; called by muse, varscan2
- IGLV2-14 | c.137G>A p.S46N | Missense Mutation (SNP) | VAF 24/56 reads (43%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.019); catalogued as rs546437688; called by muse, varscan2
- IGLV2-14 | c.148G>T p.G50C | Missense Mutation (SNP) | VAF 26/50 reads (52%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.679); catalogued as rs191388769; called by muse, varscan2
- IGLV2-14 | c.256T>C p.S86P | Missense Mutation (SNP) | VAF 25/35 reads (71%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as rs769454207; called by muse, varscan2
- IGLV3-12 | c.197T>C p.I66T | Missense Mutation (SNP) | VAF 34/34 reads (100%) | SIFT deleterious (0); PolyPhen benign (0.387); catalogued as rs1175094488; called by muse, varscan2
- IGLV3-16 | c.211G>A p.E71K | Missense Mutation (SNP) | VAF 42/90 reads (47%) | SIFT tolerated (0.75); PolyPhen benign (0.015); catalogued as rs775615687; called by muse, mutect2, varscan2
- IRX2 | c.577G>A p.E193K | Missense Mutation (SNP) | VAF 14/107 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.163); catalogued as rs913850746; called by muse, mutect2, varscan2
- ITGBL1 | c.760G>A p.D254N | Missense Mutation (SNP) | VAF 24/69 reads (35%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.932); catalogued as rs267603743, COSV66004925; called by muse, mutect2, varscan2
- KATNIP | c.3026C>G p.S1009* | Nonsense Mutation (SNP) | VAF 95/157 reads (61%) | catalogued as COSV99851186; called by muse, mutect2, varscan2
- KCNAB1 | c.418G>A p.E140K (on ENST00000490337 / NM_172160.3; = p.E129K on NM_003471.3) | Missense Mutation (SNP) | VAF 34/67 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs919946760, COSV56740913; called by muse, mutect2, varscan2
- LINGO1 | c.412G>A p.V138I | Missense Mutation (SNP) | VAF 44/103 reads (43%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.487); catalogued as rs1323181972, COSV100796526; called by muse, mutect2, varscan2
- LPAR2 | c.893G>A p.R298Q | Missense Mutation (SNP) | VAF 9/133 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.941); catalogued as rs199802494; called by muse, mutect2
- LRIG2 | c.67C>T p.R23W | Missense Mutation (SNP) | VAF 32/137 reads (23%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0); catalogued as rs766439497; called by muse, mutect2, varscan2
- LTBP1 | c.4498G>A p.D1500N (on ENST00000404816 / NM_206943.4; = p.D1174N on NM_000627.4) | Missense Mutation (SNP) | VAF 71/127 reads (56%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs568071078; called by muse, mutect2, varscan2
- MACF1 | c.18618G>C p.E6206D (on ENST00000372915; = p.E4251D on NM_012090.5) | Missense Mutation (SNP) | VAF 11/88 reads (13%) | catalogued as COSV57121032; called by muse, mutect2, varscan2
- MLF1 | c.161G>A p.R54H | Missense Mutation (SNP) | VAF 117/219 reads (53%) | SIFT tolerated (0.34); PolyPhen benign (0.015); catalogued as rs200582831, COSV63033841; called by muse, mutect2, varscan2
- MMP20 | c.494C>T p.A165V | Missense Mutation (SNP) | VAF 15/33 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs568218230; called by muse, mutect2, varscan2
- NAT10 | c.2544C>G p.I848M | Missense Mutation (SNP) | VAF 35/78 reads (45%) | SIFT tolerated (0.07); PolyPhen benign (0.01); catalogued as rs1461734477, COSV57663485; called by muse, mutect2, varscan2
- NAT10 | c.2627C>G p.S876C | Missense Mutation (SNP) | VAF 38/76 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.841); catalogued as rs753850727; called by muse, mutect2, varscan2
- NCKAP5 | c.4087G>A p.G1363R | Missense Mutation (SNP) | VAF 24/57 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.139); catalogued as COSV100491432; called by muse, mutect2, varscan2
- NEUROG1 | c.490C>T p.L164F | Missense Mutation (SNP) | VAF 22/41 reads (54%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.879); catalogued as rs1226992993; called by muse, mutect2, varscan2
- NIPA2 | c.832G>A p.D278N | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.477); catalogued as rs966212785, COSV100488860; called by muse, mutect2, varscan2
- NOM1 | c.1681C>T p.R561C | Missense Mutation (SNP) | VAF 47/126 reads (37%) | SIFT deleterious (0.05); PolyPhen benign (0.068); catalogued as rs200248456; called by muse, mutect2, varscan2
- NOSTRIN | c.1339T>G p.Y447D (on ENST00000317647 / NM_001039724.4; = p.Y369D on NM_052946.3) | Missense Mutation (SNP) | VAF 81/150 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs371977853; called by muse, mutect2, varscan2
- NPRL2 | c.640G>A p.D214N | Missense Mutation (SNP) | VAF 12/126 reads (10%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.591); catalogued as CM160819; called by muse, mutect2
- NTSR1 | c.86C>T p.A29V | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT tolerated (0.17); PolyPhen benign (0.005); catalogued as rs781334373; called by muse, mutect2, varscan2
- OR4C6 | c.605G>A p.G202E | Missense Mutation (SNP) | VAF 35/66 reads (53%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); catalogued as rs1441221580; called by muse, mutect2, varscan2
- PCDHA8 | c.2321C>T p.P774L | Missense Mutation (SNP) | VAF 30/73 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.988); catalogued as COSV65330653; called by muse, mutect2, varscan2
- PCNX2 | c.1481C>T p.S494F | Missense Mutation (SNP) | VAF 20/178 reads (11%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.087); catalogued as rs776726614; called by muse, mutect2, varscan2
- PDPR | c.1702G>C p.E568Q | Missense Mutation (SNP) | VAF 32/113 reads (28%) | SIFT tolerated (0.13); PolyPhen benign (0.092); catalogued as COSV99848801; called by muse, mutect2, varscan2
- POLR1C | c.247G>C p.E83Q | Missense Mutation (SNP) | VAF 30/156 reads (19%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.986); catalogued as rs11544826; called by muse, mutect2, varscan2
- PPP1R12C | c.1973C>T p.S658L | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.011); catalogued as COSV52382306; called by muse, mutect2, varscan2
- PRPF8 | c.6783G>A p.M2261I | Missense Mutation (SNP) | VAF 7/113 reads (6%) | SIFT tolerated (0.5); PolyPhen benign (0.297); catalogued as rs886052611; ClinVar: uncertain significance; called by muse, mutect2
- PSAPL1 | c.421G>C p.E141Q | Missense Mutation (SNP) | VAF 28/73 reads (38%) | SIFT tolerated (0.77); PolyPhen benign (0.006); catalogued as rs763618934; called by muse, mutect2, varscan2
- PTPRQ | c.5989G>A p.D1997N (on ENST00000616559; = p.D1955N on NM_001145026.2) | Missense Mutation (SNP) | VAF 30/75 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.772); catalogued as rs1238301277; called by muse, mutect2, varscan2
- RASGRP1 | c.241C>G p.R81G | Missense Mutation (SNP) | VAF 28/85 reads (33%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as COSV60364530; called by muse, mutect2, varscan2
- RHBDL1 | c.605C>T p.S202L (on ENST00000219551 / NM_001318733.2; = p.S137L on NM_001278720.2) | Missense Mutation (SNP) | VAF 24/102 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs758326393, COSV99555395; called by muse, mutect2, varscan2
- SDK1 | c.4111G>A p.E1371K | Missense Mutation (SNP) | VAF 18/34 reads (53%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.771); catalogued as COSV67373691; called by muse, mutect2
- SLCO6A1 | c.583G>A p.E195K | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT tolerated (0.57); PolyPhen possibly damaging (0.569); catalogued as COSV101134148; called by muse, mutect2
- SPTBN4 | c.2743G>A p.D915N | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.878); catalogued as COSV58950373; called by muse, mutect2, varscan2
- SSH2 | c.1061A>G p.Y354C | Missense Mutation (SNP) | VAF 50/104 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52173210; called by muse, mutect2, varscan2
- TAS1R2 | c.464C>G p.S155C | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.797); catalogued as COSV64743502; called by muse, mutect2
- TAS2R9 | c.172C>G p.L58V | Missense Mutation (SNP) | VAF 98/146 reads (67%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as COSV53690606; called by muse, mutect2, varscan2
- TMPRSS4 | c.426G>T p.Q142H | Missense Mutation (SNP) | VAF 60/129 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.838); catalogued as COSV101449401, COSV71108299; called by muse, mutect2, varscan2
- TNS2 | c.1405+3G>A | Splice Region (SNP) | VAF 31/70 reads (44%) | catalogued as rs1437400905; called by muse, mutect2, varscan2
- TPM1 | c.517G>C p.E173Q | Missense Mutation (SNP) | VAF 7/63 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV51265880; called by muse, mutect2, varscan2
- TRPM3 | c.703G>A p.D235N (on ENST00000357533 / NM_001366142.2; = p.D80N on NM_020952.6) | Missense Mutation (SNP) | VAF 61/160 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.348); catalogued as rs761902549; called by muse, mutect2, varscan2
- TTN | c.37340G>T p.G12447V (on ENST00000591111; = p.G5023V on NM_003319.4) | Missense Mutation (SNP) | VAF 11/103 reads (11%) | PolyPhen probably damaging (0.993); catalogued as COSV60276902; called by muse, mutect2
- TUBGCP5 | c.1048C>T p.P350S | Missense Mutation (SNP) | VAF 11/110 reads (10%) | SIFT tolerated (0.29); PolyPhen benign (0.01); catalogued as rs1440625407; called by muse, mutect2, varscan2
- UGGT2 | c.309C>G p.I103M | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT tolerated (0.13); PolyPhen benign (0.029); catalogued as COSV100942596; called by muse, mutect2, varscan2
- USF3 | c.4829G>A p.R1610K | Missense Mutation (SNP) | VAF 88/185 reads (48%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.995); catalogued as COSV57069362; called by muse, mutect2, varscan2
- USP9X | c.7306C>T p.Q2436* | Nonsense Mutation (SNP) | VAF 43/70 reads (61%) | catalogued as COSV61073655; called by muse, mutect2, varscan2
- XRCC3 | c.775-2A>G p.X259_splice | Splice Site (SNP) | VAF 31/54 reads (57%) | catalogued as rs1404709980, COSV100572868; called by muse, mutect2, varscan2
- ADAMTS18 | c.1787C>G p.S596W | Missense Mutation (SNP) | VAF 18/112 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.445); called by muse, mutect2, varscan2
- ADAMTSL2 | c.706C>G p.P236A | Missense Mutation (SNP) | VAF 10/109 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ADCY2 | c.3260G>A p.S1087N | Missense Mutation (SNP) | VAF 49/108 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.07); called by muse, mutect2, varscan2
- ADGRG6 | c.141C>A p.N47K | Missense Mutation (SNP) | VAF 33/75 reads (44%) | SIFT tolerated (0.31); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- AFTPH | c.1063G>T p.E355* | Nonsense Mutation (SNP) | VAF 106/221 reads (48%) | called by muse, mutect2, varscan2
- AHDC1 | c.70G>A p.E24K | Missense Mutation (SNP) | VAF 27/48 reads (56%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- ARHGAP32 | c.3307C>A p.P1103T (on ENST00000310343 / NM_001378025.1; = p.P754T on NM_014715.4) | Missense Mutation (SNP) | VAF 116/236 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.051); called by muse, mutect2, varscan2
- ARHGEF19 | c.1948G>A p.E650K | Missense Mutation (SNP) | VAF 26/51 reads (51%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.621); called by muse, mutect2, varscan2
- ATAD2 | c.3327G>C p.K1109N | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.119); called by muse, mutect2, varscan2
- ATF7 | c.49-1G>A p.X17_splice | Splice Site (SNP) | VAF 36/94 reads (38%) | called by muse, mutect2, varscan2
- ATOH1 | c.266C>A p.A89D | Missense Mutation (SNP) | VAF 28/53 reads (53%) | SIFT deleterious (0); PolyPhen benign (0.216); called by muse, mutect2, varscan2
- AWAT2 | c.648-6C>T | Splice Region (SNP) | VAF 9/56 reads (16%) | called by muse, mutect2, varscan2
- AXDND1 | c.362C>G p.T121R | Missense Mutation (SNP) | VAF 25/49 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.497); called by muse, mutect2, varscan2
- BIRC2 | c.1699G>T p.E567* | Nonsense Mutation (SNP) | VAF 8/56 reads (14%) | called by muse, mutect2, varscan2
- BRIP1 | c.886G>A p.E296K | Missense Mutation (SNP) | VAF 24/82 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- BTBD11 | c.2521C>G p.L841V (on ENST00000280758 / NM_001018072.2; = p.L378V on NM_001017523.2) | Missense Mutation (SNP) | VAF 27/62 reads (44%) | SIFT tolerated (1); PolyPhen benign (0.185); called by muse, mutect2, varscan2
- C2orf42 | c.990G>C p.R330S | Missense Mutation (SNP) | VAF 79/139 reads (57%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.943); called by muse, mutect2, varscan2
- CARD10 | c.1948-7C>T | Splice Region (SNP) | VAF 21/55 reads (38%) | called by muse, mutect2, varscan2
- CASR | c.2921C>A p.S974Y (on ENST00000490131; = p.S1051Y on NM_000388.4) | Missense Mutation (SNP) | VAF 43/88 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.176); called by muse, mutect2, varscan2
- CEP70 | c.82G>C p.E28Q | Missense Mutation (SNP) | VAF 3/31 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); called by muse, mutect2
- CLDN2 | c.654G>C p.K218N | Missense Mutation (SNP) | VAF 7/119 reads (6%) | SIFT tolerated (0.05); PolyPhen benign (0.043); called by muse, mutect2
- CRYBA1 | c.152C>G p.S51C | Missense Mutation (SNP) | VAF 7/65 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CSF3R | c.2107G>A p.E703K | Missense Mutation (SNP) | VAF 5/89 reads (6%) | SIFT tolerated (0.13); PolyPhen benign (0.026); called by muse, mutect2
- CST9L | c.400C>G p.Q134E | Missense Mutation (SNP) | VAF 3/27 reads (11%) | SIFT tolerated (0.71); PolyPhen benign (0.001); called by muse, mutect2
- CTSB | c.-25-4C>G | Splice Region (SNP) | VAF 9/75 reads (12%) | called by muse, varscan2
- DDX21 | c.196G>C p.E66Q | Missense Mutation (SNP) | VAF 3/37 reads (8%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.478); called by muse, mutect2
- DDX39A | c.131C>G p.S44C | Missense Mutation (SNP) | VAF 15/86 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); called by muse, mutect2, varscan2
- DDX55 | c.1334-1G>C p.X445_splice | Splice Site (SNP) | VAF 6/38 reads (16%) | called by muse, mutect2, varscan2
- DGKD | c.2743C>T p.Q915* (on ENST00000264057 / NM_152879.3; = p.Q871* on NM_003648.3 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 31/64 reads (48%) | called by muse, mutect2, varscan2
- DMXL2 | c.7837C>T p.R2613* | Nonsense Mutation (SNP) | VAF 22/35 reads (63%) | called by muse, mutect2, varscan2
- DNAH11 | c.6648C>G p.F2216L | Missense Mutation (SNP) | VAF 54/175 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.675); called by muse, mutect2, varscan2
- DNAH8 | c.1976C>T p.S659F | Missense Mutation (SNP) | VAF 42/100 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.361); called by muse, mutect2, varscan2
- DOCK6 | c.5506G>A p.D1836N | Missense Mutation (SNP) | VAF 69/139 reads (50%) | SIFT tolerated (0.14); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- DPY19L2 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 6/30 reads (20%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.107); called by muse, mutect2, varscan2
- EEF2K | c.1268C>G p.S423C | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT deleterious (0.05); PolyPhen benign (0.198); called by muse, mutect2, varscan2
- ESCO1 | c.1609C>T p.Q537* | Nonsense Mutation (SNP) | VAF 5/64 reads (8%) | called by muse, mutect2
- FAM126B | c.1426G>A p.G476S | Missense Mutation (SNP) | VAF 75/144 reads (52%) | SIFT tolerated (0.74); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- FAM20C | c.1406G>A p.G469E | Missense Mutation (SNP) | VAF 10/121 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2
- FILIP1 | c.2887C>G p.Q963E | Missense Mutation (SNP) | VAF 37/188 reads (20%) | SIFT tolerated (0.91); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- GMEB1 | c.1403C>T p.S468L | Missense Mutation (SNP) | VAF 42/79 reads (53%) | SIFT deleterious (0.01); PolyPhen benign (0.407); called by muse, mutect2, varscan2
- GNAQ | c.977C>G p.S326C | Missense Mutation (SNP) | VAF 37/77 reads (48%) | SIFT tolerated (0.13); PolyPhen benign (0.14); called by muse, mutect2, varscan2
- GOLGA4 | c.2409del p.Q804Sfs*53 | Frame Shift Del (DEL) | VAF 131/275 reads (48%) | called by mutect2, pindel, varscan2
- HMCN2 | c.13748C>A p.S4583* | Nonsense Mutation (SNP) | VAF 28/66 reads (42%) | called by muse, mutect2, varscan2
- INTS12 | c.106G>A p.D36N | Missense Mutation (SNP) | VAF 97/198 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- IPO4 | c.2155G>A p.E719K | Missense Mutation (SNP) | VAF 6/61 reads (10%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.546); called by muse, mutect2, varscan2
- KIF11 | c.2698G>A p.E900K | Missense Mutation (SNP) | VAF 42/67 reads (63%) | SIFT tolerated (0.17); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- LNPEP | c.2410C>G p.Q804E | Missense Mutation (SNP) | VAF 5/105 reads (5%) | SIFT tolerated (0.08); PolyPhen benign (0.01); called by muse, mutect2
- LRRC17 | c.1181G>C p.R394T | Missense Mutation (SNP) | VAF 55/218 reads (25%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.879); called by muse, mutect2, varscan2
- MACF1 | c.1210G>A p.E404K | Missense Mutation (SNP) | VAF 7/112 reads (6%) | called by muse, mutect2
- MACROH2A2 | c.718G>C p.E240Q | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.707); called by muse, mutect2, varscan2
- MAP3K14 | c.548C>G p.S183C | Missense Mutation (SNP) | VAF 52/106 reads (49%) | SIFT deleterious (0.02); PolyPhen benign (0); called by muse, mutect2, varscan2
- METTL11B | c.93C>A p.H31Q | Missense Mutation (SNP) | VAF 72/161 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- MICAL2 | c.4013G>A p.R1338K | Missense Mutation (SNP) | VAF 56/104 reads (54%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- MRAP2 | c.383G>C p.R128T | Missense Mutation (SNP) | VAF 8/101 reads (8%) | SIFT tolerated (0.09); PolyPhen benign (0.047); called by muse, mutect2
- MUC1 | c.209C>G p.S70C | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.968); called by mutect2, varscan2
- MYRF | c.3253G>A p.E1085K (on ENST00000278836 / NM_001127392.3; = p.E1045K on NM_013279.4) | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT tolerated (0.24); PolyPhen benign (0.075); called by muse, mutect2, varscan2
- N4BP1 | c.478T>G p.F160V | Missense Mutation (SNP) | VAF 87/162 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- NBEA | c.3505C>G p.P1169A | Missense Mutation (SNP) | VAF 25/71 reads (35%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0); called by muse, mutect2, varscan2
- NKRF | c.1399G>C p.E467Q | Missense Mutation (SNP) | VAF 84/219 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- NOS1 | c.997G>A p.E333K | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT tolerated (0.36); PolyPhen benign (0.006); called by muse, mutect2
- NR2F1 | c.1242C>A p.N414K | Missense Mutation (SNP) | VAF 47/134 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.164); called by muse, mutect2, varscan2
- OBSCN | c.16034C>G p.S5345C | Missense Mutation (SNP) | VAF 5/52 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2
- OR4C5 | c.373G>A p.E125K | Missense Mutation (SNP) | VAF 56/178 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.133); called by muse, mutect2, varscan2
- PAQR3 | c.305G>A p.R102K | Missense Mutation (SNP) | VAF 61/137 reads (45%) | SIFT tolerated (0.29); PolyPhen benign (0.143); called by muse, mutect2, varscan2
- PCNX4 | c.817G>C p.E273Q (on ENST00000406854 / NM_001330177.2; = p.E39Q on NM_022495.5) | Missense Mutation (SNP) | VAF 26/159 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PDCD10 | c.550G>A p.D184N | Missense Mutation (SNP) | VAF 12/159 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.917); called by muse, mutect2
- PHF8 | c.27G>C p.Q9H | Missense Mutation (SNP) | VAF 12/76 reads (16%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.36); called by muse, mutect2, varscan2
- PKD1L1 | c.223C>G p.L75V | Missense Mutation (SNP) | VAF 68/125 reads (54%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.099); called by muse, mutect2, varscan2
- PLAA | c.884G>C p.R295T | Missense Mutation (SNP) | VAF 9/88 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- PLPP4 | c.400C>G p.L134V | Missense Mutation (SNP) | VAF 31/51 reads (61%) | SIFT tolerated (1); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- PTPRZ1 | c.1705G>A p.E569K | Missense Mutation (SNP) | VAF 5/84 reads (6%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.188); called by muse, mutect2
- QDPR | c.226G>A p.G76S | Missense Mutation (SNP) | VAF 60/136 reads (44%) | SIFT tolerated (0.18); PolyPhen benign (0.213); called by muse, mutect2
- RABGAP1L | c.50T>C p.V17A | Missense Mutation (SNP) | VAF 78/160 reads (49%) | SIFT deleterious (0.02); PolyPhen benign (0); called by muse, mutect2, varscan2
- RELT | c.355C>G p.H119D | Missense Mutation (SNP) | VAF 40/77 reads (52%) | SIFT tolerated (0.63); PolyPhen benign (0); called by muse, mutect2, varscan2
- RIPOR3 | c.2788G>C p.E930Q | Missense Mutation (SNP) | VAF 50/96 reads (52%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.776); called by muse, varscan2
- RNF17 | c.4059T>G p.Y1353* | Nonsense Mutation (SNP) | VAF 14/30 reads (47%) | called by muse, mutect2, varscan2
- RPRD2 | c.2873C>A p.P958Q | Missense Mutation (SNP) | VAF 10/206 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); called by muse, mutect2
- SAPCD1 | c.308T>C p.I103T | Missense Mutation (SNP) | VAF 63/133 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- SCN1A | c.2758G>T p.V920F (on ENST00000303395 / NM_001202435.3; = p.V909F on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/88 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.345); called by muse, mutect2, varscan2
- SLCO2A1 | c.1387G>A p.G463R | Missense Mutation (SNP) | VAF 36/66 reads (55%) | SIFT tolerated (0.11); PolyPhen benign (0.393); called by muse, mutect2, varscan2
- SORBS1 | c.988C>G p.P330A (on ENST00000361941 / NM_001034954.2; = p.P166A on NM_006434.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.059); called by muse, mutect2
- STAG1 | c.1570G>A p.A524T | Missense Mutation (SNP) | VAF 53/94 reads (56%) | SIFT tolerated (0.53); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- TAF6L | c.1723G>A p.G575R | Missense Mutation (SNP) | VAF 49/108 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); called by muse, mutect2, varscan2
- TBC1D17 | c.1270C>T p.L424F | Missense Mutation (SNP) | VAF 74/147 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- TEX55 | c.1576G>C p.E526Q | Missense Mutation (SNP) | VAF 136/307 reads (44%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- TLN1 | c.2657A>C p.Q886P | Missense Mutation (SNP) | VAF 15/28 reads (54%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.658); called by muse, mutect2, varscan2
- TMEM231 | c.319G>A p.E107K (on ENST00000258173 / NM_001077418.3; = p.E136K on NM_001077416.2) | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.284); called by muse, varscan2
- TNR | c.75G>C p.M25I | Missense Mutation (SNP) | VAF 28/167 reads (17%) | SIFT tolerated, low confidence (0.69); PolyPhen benign (0); called by muse, mutect2, varscan2
- TOP2B | c.4379-1G>C p.X1460_splice (on ENST00000264331 / NM_001330700.2; = p.X1455_splice on NM_001068.3) | Splice Site (SNP) | VAF 14/32 reads (44%) | called by muse, mutect2, varscan2
- TSC22D1 | c.1247C>G p.S416C | Missense Mutation (SNP) | VAF 103/106 reads (97%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- TTN | c.56125C>G p.L18709V (on ENST00000591111; = p.L11285V on NM_003319.4) | Missense Mutation (SNP) | VAF 15/122 reads (12%) | PolyPhen benign (0.047); called by muse, mutect2, varscan2
- UBR4 | c.3537A>C p.Q1179H | Missense Mutation (SNP) | VAF 60/121 reads (50%) | SIFT tolerated (0.48); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- UNC5D | c.809G>A p.R270K | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT tolerated (0.11); PolyPhen benign (0.176); called by muse, mutect2
- UPF1 | c.1063G>T p.E355* | Nonsense Mutation (SNP) | VAF 15/78 reads (19%) | called by muse, mutect2, varscan2
- VCAN | c.4159G>A p.E1387K | Missense Mutation (SNP) | VAF 63/122 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.84); called by muse, mutect2, varscan2
- VNN1 | c.965G>A p.S322N | Missense Mutation (SNP) | VAF 87/175 reads (50%) | SIFT tolerated (0.17); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- VPS13D | c.4627G>A p.E1543K | Missense Mutation (SNP) | VAF 6/125 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); called by muse, mutect2
- VPS33A | c.1570G>A p.E524K | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- WDR74 | c.516+3G>A | Splice Region (SNP) | VAF 20/117 reads (17%) | called by muse, mutect2, varscan2
- WHAMM | c.1930C>G p.P644A | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.513); called by muse, mutect2, varscan2
- XPC | c.2716C>G p.Q906E | Missense Mutation (SNP) | VAF 39/87 reads (45%) | SIFT deleterious (0.03); PolyPhen benign (0.406); called by muse, mutect2, varscan2
- ZBTB21 | c.2798C>G p.S933C | Missense Mutation (SNP) | VAF 7/75 reads (9%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.862); called by muse, mutect2
- ZBTB21 | c.2360C>G p.S787C | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); called by muse, mutect2, varscan2
- ZBTB41 | c.1033C>G p.H345D | Missense Mutation (SNP) | VAF 17/259 reads (7%) | SIFT tolerated (0.22); PolyPhen benign (0.005); called by muse, mutect2
- ZNF181 | c.1308G>C p.Q436H | Missense Mutation (SNP) | VAF 14/205 reads (7%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.916); called by muse, mutect2
- ZNF226 | c.1295C>G p.S432* | Nonsense Mutation (SNP) | VAF 17/148 reads (11%) | called by muse, mutect2, varscan2
- ZNF280A | c.311C>G p.S104C | Missense Mutation (SNP) | VAF 6/99 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.948); called by muse, mutect2
- ZNF418 | c.1561C>G p.Q521E | Missense Mutation (SNP) | VAF 65/198 reads (33%) | SIFT tolerated (0.91); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- ZNF510 | c.307G>C p.E103Q | Missense Mutation (SNP) | VAF 14/84 reads (17%) | SIFT tolerated (0.12); PolyPhen benign (0.401); called by muse, mutect2, varscan2
- ZNF546 | c.1660G>A p.E554K | Missense Mutation (SNP) | VAF 46/121 reads (38%) | SIFT tolerated (0.29); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF80 | c.241G>C p.E81Q | Missense Mutation (SNP) | VAF 33/62 reads (53%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.675); called by muse, mutect2, varscan2
- ZRANB3 | c.1907C>T p.S636L | Missense Mutation (SNP) | VAF 19/99 reads (19%) | SIFT tolerated (0.16); PolyPhen benign (0.124); called by muse, mutect2
- ADGRA2 | c.1755G>A p.E585= | Silent (SNP) | VAF 20/39 reads (51%) | catalogued as rs149384087; called by muse, mutect2, varscan2
- ANKRD12 | c.3801T>A p.A1267= | Silent (SNP) | VAF 9/134 reads (7%) | called by muse, mutect2
- B4GALNT3 | c.1686G>A p.L562= | Silent (SNP) | VAF 8/67 reads (12%) | called by muse, mutect2, varscan2
- BRCA1 | c.4554G>A p.Q1518= | Silent (SNP) | VAF 5/94 reads (5%) | catalogued as rs786202635; ClinVar: likely benign; called by muse, mutect2
- CCKBR | c.756C>T p.D252= | Silent (SNP) | VAF 58/121 reads (48%) | catalogued as rs747685589, COSV58100637; called by muse, mutect2, varscan2
- CCNE1 | c.648G>C p.V216= | Silent (SNP) | VAF 34/68 reads (50%) | catalogued as COSV52904791; called by muse, mutect2, varscan2
- CD99L2 | c.36C>T p.L12= | Silent (SNP) | VAF 12/14 reads (86%) | called by muse, mutect2, varscan2
- CDH8 | c.168G>A p.L56= | Silent (SNP) | VAF 35/186 reads (19%) | catalogued as COSV100181538, COSV54867130, COSV54868486; called by muse, mutect2, varscan2
- CDHR4 | c.1371G>A p.A457= | Silent (SNP) | VAF 49/107 reads (46%) | catalogued as rs535266119, COSV58526451; called by muse, mutect2, varscan2
- CELSR3 | c.7842C>T p.L2614= | Silent (SNP) | VAF 16/89 reads (18%) | catalogued as rs1238455954; called by muse, mutect2, varscan2
- COL6A2 | c.411G>A p.A137= | Silent (SNP) | VAF 62/115 reads (54%) | catalogued as rs528885146; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COQ4 | c.789C>T p.G263= | Silent (SNP) | VAF 22/45 reads (49%) | called by muse, mutect2, varscan2
- CS | c.1095G>A p.L365= | Silent (SNP) | VAF 41/92 reads (45%) | catalogued as COSV57525570; called by muse, mutect2, varscan2
- DCAF12 | c.666G>A p.A222= | Silent (SNP) | VAF 6/45 reads (13%) | catalogued as rs775264703, COSV63512408; called by muse, mutect2, varscan2
- DLK1 | c.1122C>T p.F374= | Silent (SNP) | VAF 33/165 reads (20%) | catalogued as COSV57992107; called by muse, mutect2, varscan2
- DNAH2 | c.8004C>A p.I2668= | Silent (SNP) | VAF 67/125 reads (54%) | called by muse, mutect2, varscan2
- DNAH8 | c.11277G>A p.L3759= | Silent (SNP) | VAF 60/116 reads (52%) | called by muse, mutect2, varscan2
- DYSF | c.21C>G p.L7= | Silent (SNP) | VAF 14/202 reads (7%) | called by muse, mutect2
- DYSF | c.3663G>A p.P1221= | Silent (SNP) | VAF 51/97 reads (53%) | catalogued as rs150444588, COSV50282744; called by muse, mutect2, varscan2
- EIF2B2 | c.372C>T p.F124= | Silent (SNP) | VAF 11/75 reads (15%) | catalogued as rs769455036; called by muse, mutect2, varscan2
- FBN3 | c.6786C>T p.L2262= | Silent (SNP) | VAF 19/91 reads (21%) | called by muse, mutect2, varscan2
- FBXO17 | c.426G>A p.G142= | Silent (SNP) | VAF 38/87 reads (44%) | called by muse, varscan2
- FCGBP | c.1254C>T p.F418= | Silent (SNP) | VAF 33/61 reads (54%) | catalogued as rs753966005; called by muse, mutect2, varscan2
- FRAS1 | c.9306G>A p.K3102= | Silent (SNP) | VAF 16/111 reads (14%) | called by muse, mutect2, varscan2
- FSCN1 | c.1335C>T p.G445= | Silent (SNP) | VAF 9/75 reads (12%) | called by muse, mutect2, varscan2
- FYB1 | c.2118A>G p.R706= (on ENST00000351578 / NM_199335.5; = p.R752= on NM_001465.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 6/17 reads (35%) | catalogued as COSV100686526; called by muse, mutect2, varscan2
- GRAMD1B | c.516C>T p.I172= | Silent (SNP) | VAF 107/195 reads (55%) | catalogued as COSV59201585; called by muse, mutect2, varscan2
- HIRA | c.1848G>A p.E616= | Silent (SNP) | VAF 26/38 reads (68%) | called by muse, mutect2, varscan2
- IGLV3-12 | c.183C>T p.D61= | Silent (SNP) | VAF 38/38 reads (100%) | called by muse, varscan2
- ILDR1 | c.552G>A p.L184= | Silent (SNP) | VAF 12/72 reads (17%) | called by muse, mutect2, varscan2
- INTS9 | c.294G>C p.V98= | Silent (SNP) | VAF 3/30 reads (10%) | called by muse, mutect2
- KMT5B | c.1779G>A p.E593= | Silent (SNP) | VAF 8/124 reads (6%) | called by muse, mutect2
- KMT5B | c.1644G>C p.L548= | Silent (SNP) | VAF 9/98 reads (9%) | called by muse, mutect2
- KNDC1 | c.5061G>A p.E1687= | Silent (SNP) | VAF 29/118 reads (25%) | called by muse, mutect2, varscan2
- KRTAP20-2 | c.197G>A p.*66= | Silent (SNP) | VAF 9/99 reads (9%) | catalogued as rs752395885, COSV100424546; called by muse, mutect2
- KRTAP4-5 | c.27C>G p.V9= | Silent (SNP) | VAF 58/122 reads (48%) | catalogued as COSV58353287; called by muse, mutect2
- LBX1 | c.144G>A p.R48= | Silent (SNP) | VAF 29/86 reads (34%) | catalogued as rs1279469207; called by muse, mutect2, varscan2
- LRRC43 | c.1641G>A p.K547= | Silent (SNP) | VAF 4/41 reads (10%) | catalogued as COSV100148835; called by mutect2, varscan2
- LTK | c.720G>A p.L240= | Silent (SNP) | VAF 9/40 reads (23%) | called by muse, mutect2, varscan2
- MARCHF6 | c.1326G>A p.L442= | Silent (SNP) | VAF 48/86 reads (56%) | catalogued as COSV56887740; called by muse, mutect2, varscan2
- MUC5B | c.14361C>T p.T4787= | Silent (SNP) | VAF 92/204 reads (45%) | catalogued as rs1318193292; called by muse, mutect2, varscan2
- MUC7 | c.183G>A p.K61= | Silent (SNP) | VAF 28/218 reads (13%) | called by muse, mutect2, varscan2
- MYCBP2 | c.3858C>T p.L1286= (on ENST00000357337; = p.L1324= on NM_015057.5) | Silent (SNP) | VAF 20/50 reads (40%) | called by muse, mutect2, varscan2
- MYO5C | c.4665G>C p.L1555= | Silent (SNP) | VAF 53/84 reads (63%) | called by muse, mutect2, varscan2
- NECTIN4 | c.348C>T p.N116= | Silent (SNP) | VAF 39/60 reads (65%) | catalogued as rs762500186, COSV63512951; called by muse, mutect2, varscan2
- NR1H3 | c.939C>T p.I313= | Silent (SNP) | VAF 13/103 reads (13%) | called by muse, mutect2, varscan2
- NUP188 | c.1947G>A p.L649= | Silent (SNP) | VAF 6/69 reads (9%) | called by muse, mutect2
- OR1S2 | c.942G>A p.L314= | Silent (SNP) | VAF 105/217 reads (48%) | called by muse, mutect2, varscan2
- OR51E1 | c.723C>A p.G241= | Silent (SNP) | VAF 22/80 reads (28%) | called by muse, mutect2, varscan2
- OSBPL3 | c.1461C>T p.L487= | Silent (SNP) | VAF 21/32 reads (66%) | called by muse, mutect2, varscan2
- PIEZO2 | c.5034T>C p.S1678= | Silent (SNP) | VAF 23/57 reads (40%) | called by muse, mutect2, varscan2
- PLCB1 | c.2352G>A p.L784= | Silent (SNP) | VAF 3/42 reads (7%) | called by muse, mutect2
- PRKDC | c.7188C>T p.L2396= | Silent (SNP) | VAF 32/163 reads (20%) | called by muse, mutect2, varscan2
- PROCR | c.150G>A p.L50= | Silent (SNP) | VAF 20/113 reads (18%) | called by muse, mutect2, varscan2
- PRR14 | c.381G>C p.L127= | Silent (SNP) | VAF 13/84 reads (15%) | called by muse, mutect2, varscan2
- RIF1 | c.6921T>G p.P2307= | Silent (SNP) | VAF 21/186 reads (11%) | called by muse, mutect2, varscan2
- RIPK4 | c.2184C>T p.N728= (on ENST00000352483; = p.N680= on NM_020639.3) | Silent (SNP) | VAF 57/97 reads (59%) | catalogued as rs781354643, COSV60186631; called by muse, mutect2, varscan2
- SETD2 | c.5085C>T p.V1695= | Silent (SNP) | VAF 28/175 reads (16%) | called by muse, mutect2, varscan2
- SIRPB1 | c.1056G>A p.Q352= | Silent (SNP) | VAF 31/31 reads (100%) | catalogued as rs1185795368; called by muse, mutect2, varscan2
- SLC39A5 | c.1230C>T p.F410= | Silent (SNP) | VAF 38/57 reads (67%) | called by muse, mutect2, varscan2
- SLTM | c.1386T>G p.G462= | Silent (SNP) | VAF 7/13 reads (54%) | called by muse, mutect2, varscan2
- SOWAHA | c.1527G>A p.S509= | Silent (SNP) | VAF 56/128 reads (44%) | catalogued as rs1023840661, COSV66332421; called by muse, mutect2, varscan2
- SRPRB | c.475C>T p.L159= | Silent (SNP) | VAF 22/180 reads (12%) | called by muse, mutect2, varscan2
- TMEM132C | c.3006G>A p.P1002= | Silent (SNP) | VAF 44/110 reads (40%) | catalogued as rs551480348, COSV59423367; called by muse, mutect2, varscan2
- TRIM10 | c.54C>T p.I18= | Silent (SNP) | VAF 4/53 reads (8%) | called by muse, mutect2
- TTYH2 | c.471C>T p.L157= | Silent (SNP) | VAF 48/109 reads (44%) | called by muse, mutect2, varscan2
- VSIG2 | c.702G>A p.V234= | Silent (SNP) | VAF 46/102 reads (45%) | catalogued as rs527352600; called by muse, mutect2, varscan2
- WDR24 | c.12G>A p.K4= | Silent (SNP) | VAF 50/87 reads (57%) | catalogued as rs1253651201; called by muse, mutect2, varscan2
- WDR49 | c.1020C>T p.L340= (on ENST00000308378 / NM_001366158.1; = p.L681= on NM_001348951.2 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 3/14 reads (21%) | catalogued as COSV57719388; called by muse, mutect2
- WHRN | c.342C>G p.L114= | Silent (SNP) | VAF 9/79 reads (11%) | catalogued as rs368710698; called by muse, mutect2, varscan2
- ZFP36L2 | c.822C>G p.L274= | Silent (SNP) | VAF 6/50 reads (12%) | catalogued as rs746491242; called by muse, mutect2, varscan2
- ZFX | c.708G>A p.S236= | Silent (SNP) | VAF 19/45 reads (42%) | catalogued as rs779840420; called by muse, mutect2, varscan2
- ABCA2 | chr9:137032486 G>C | 5'Flank (SNP) | VAF 23/52 reads (44%) | called by muse, mutect2, varscan2
- ABLIM2 | c.*560T>C | 3'UTR (SNP) | VAF 11/137 reads (8%) | called by muse, mutect2
- AC004899.2 | chr7:48846468 G>A | 5'Flank (SNP) | VAF 8/117 reads (7%) | called by muse, mutect2
- AC093890.1 | n.476A>C | RNA (SNP) | VAF 33/72 reads (46%) | called by muse, mutect2, varscan2
- AC093890.1 | n.354A>G | RNA (SNP) | VAF 49/112 reads (44%) | called by muse, mutect2, varscan2
- AC133561.1 | n.113C>T | RNA (SNP) | VAF 10/15 reads (67%) | called by mutect2, varscan2
- ADRA2A | c.*831C>T | 3'UTR (SNP) | VAF 31/83 reads (37%) | called by muse, mutect2, varscan2
- AGXT | c.847-327C>G | Intron (SNP) | VAF 36/116 reads (31%) | called by muse, mutect2, varscan2
- AK7 | c.294+339C>T | Intron (SNP) | VAF 11/29 reads (38%) | called by muse, mutect2, varscan2
- ALDH1A3 | c.99+516G>A | Intron (SNP) | VAF 19/75 reads (25%) | catalogued as rs987992814; called by muse, mutect2, varscan2
- ANKRD37 | c.-5G>A | 5'UTR (SNP) | VAF 7/50 reads (14%) | catalogued as rs371815282; called by muse, mutect2, varscan2
- ANKRD50 | c.-217C>T | 5'UTR (SNP) | VAF 26/61 reads (43%) | called by muse, mutect2, varscan2
- ARFGEF3 | c.*8047G>T | 3'UTR (SNP) | VAF 8/92 reads (9%) | called by muse, mutect2
- ARL4C | c.*87G>A | 3'UTR (SNP) | VAF 20/167 reads (12%) | called by muse, mutect2, varscan2
- ARPP21 | c.261+1808T>C | Intron (SNP) | VAF 5/78 reads (6%) | called by muse, mutect2
- ARSB | c.1213+23475T>G | Intron (SNP) | VAF 30/58 reads (52%) | called by muse, mutect2, varscan2
- ASTN2 | c.*365C>A | 3'UTR (SNP) | VAF 10/107 reads (9%) | catalogued as COSV99941634; called by muse, mutect2, varscan2
- ATF4 | c.-699A>C | 5'UTR (SNP) | VAF 32/62 reads (52%) | called by muse, mutect2, varscan2
- ATP13A3 | c.*2320G>C | 3'UTR (SNP) | VAF 7/58 reads (12%) | called by muse, mutect2, varscan2
- ATXN2L | c.300-762C>T | Intron (SNP) | VAF 26/58 reads (45%) | called by muse, mutect2, varscan2
- ATXN7L3B | c.*1294G>A | 3'UTR (SNP) | VAF 8/23 reads (35%) | called by muse, mutect2, varscan2
- AZIN1 | c.*2014G>A | 3'UTR (SNP) | VAF 22/55 reads (40%) | called by muse, mutect2, varscan2
- BAIAP2L2 | c.*270C>G | 3'UTR (SNP) | VAF 31/59 reads (53%) | called by muse, mutect2, varscan2
- BEAN1 | c.25+97G>T | Intron (SNP) | VAF 25/75 reads (33%) | called by muse, mutect2, varscan2
- BPNT2 | c.*896C>T | 3'UTR (SNP) | VAF 11/143 reads (8%) | called by muse, mutect2
- BTBD9 | c.*6260C>A | 3'UTR (SNP) | VAF 47/98 reads (48%) | called by muse, mutect2, varscan2
- C1orf52 | c.-28G>A | 5'UTR (SNP) | VAF 25/52 reads (48%) | called by muse, mutect2, varscan2
- C5orf64 | n.513-43424T>G | Intron (SNP) | VAF 14/111 reads (13%) | called by muse, mutect2, varscan2
- CABP4 | c.*317G>A | 3'UTR (SNP) | VAF 4/48 reads (8%) | called by muse, mutect2
- CACNA2D1 | chr7:81949668 G>A | 3'Flank (SNP) | VAF 69/105 reads (66%) | called by muse, mutect2, varscan2
- CAMKK1 | c.*1668G>A | 3'UTR (SNP) | VAF 3/34 reads (9%) | called by muse, mutect2
- CCDC163 | c.*166C>G | 3'UTR (SNP) | VAF 3/29 reads (10%) | catalogued as rs1340854038; called by muse, mutect2
- CDK11B | c.495-884G>C | Intron (SNP) | VAF 9/22 reads (41%) | called by muse, mutect2, varscan2
- CDK16 | c.1454-16C>T | Intron (SNP) | VAF 28/145 reads (19%) | called by muse, mutect2, varscan2
- CENPA | c.211-94G>C | Intron (SNP) | VAF 47/117 reads (40%) | called by muse, mutect2, varscan2
- CEP97 | c.*438G>C | 3'UTR (SNP) | VAF 5/91 reads (5%) | catalogued as COSV59127629; called by muse, mutect2
- CHTOP | c.542-812G>C | Intron (SNP) | VAF 36/70 reads (51%) | called by muse, mutect2, varscan2
- CLIC2 | c.*1620A>G | 3'UTR (SNP) | VAF 20/42 reads (48%) | called by muse, mutect2, varscan2
- CLIC5 | c.*348G>C | 3'UTR (SNP) | VAF 14/77 reads (18%) | called by muse, mutect2, varscan2
- CLIP4 | c.*272C>T | 3'UTR (SNP) | VAF 5/65 reads (8%) | catalogued as rs984559682; called by muse, mutect2
- COL11A1 | c.*1538T>C | 3'UTR (SNP) | VAF 37/77 reads (48%) | catalogued as COSV62192798; called by muse, mutect2, varscan2
- COPE | c.*18C>G | 3'UTR (SNP) | VAF 11/54 reads (20%) | called by muse, mutect2, varscan2
- CPEB1 | c.371-1590C>G | Intron (SNP) | VAF 7/55 reads (13%) | catalogued as rs1471442296; called by muse, mutect2, varscan2
- CRKL | chr22:20957442 C>T | 3'Flank (SNP) | VAF 51/84 reads (61%) | called by muse, mutect2, varscan2
- CSMD3 | c.*254G>A | 3'UTR (SNP) | VAF 23/53 reads (43%) | called by muse, mutect2, varscan2
- CTSA | chr20:45891137 C>T | 5'Flank (SNP) | VAF 57/112 reads (51%) | catalogued as COSV99509979; called by muse, mutect2, varscan2
- CYP4F3 | c.*56G>C | 3'UTR (SNP) | VAF 42/95 reads (44%) | called by muse, mutect2, varscan2
- CYP4V2 | c.605-18C>T | Intron (SNP) | VAF 89/173 reads (51%) | called by muse, mutect2, varscan2
- CYRIA | c.*3212C>T | 3'UTR (SNP) | VAF 17/99 reads (17%) | called by muse, mutect2
- DAZL | c.-29C>T | 5'UTR (SNP) | VAF 61/126 reads (48%) | called by muse, mutect2, varscan2
- DCBLD2 | c.*2971G>A | 3'UTR (SNP) | VAF 41/82 reads (50%) | called by muse, mutect2, varscan2
- DCLRE1A | c.-222del | 5'UTR (DEL) | VAF 9/66 reads (14%) | called by mutect2, pindel, varscan2
- DDR1 | c.*128G>A | 3'UTR (SNP) | VAF 8/60 reads (13%) | called by muse, mutect2, varscan2
- DIS3 | c.*1550G>A | 3'UTR (SNP) | VAF 36/64 reads (56%) | called by muse, mutect2, varscan2
- DOCK9 | c.*1260T>C | 3'UTR (SNP) | VAF 4/37 reads (11%) | called by muse, mutect2
- DOT1L | c.*1187C>G | 3'UTR (SNP) | VAF 15/71 reads (21%) | called by muse, mutect2, varscan2
- DTNA | c.1662+4332G>T | Intron (SNP) | VAF 17/30 reads (57%) | catalogued as rs960327352; called by muse, mutect2, varscan2
- EAF1 | c.*352C>T | 3'UTR (SNP) | VAF 17/52 reads (33%) | called by muse, mutect2, varscan2
- EFCAB3 | c.*77C>T | 3'UTR (SNP) | VAF 6/76 reads (8%) | called by muse, mutect2
- EIF2B5 | c.1893+155G>C | Intron (SNP) | VAF 7/11 reads (64%) | called by muse, mutect2
- EPHA3 | c.*1041C>A | 3'UTR (SNP) | VAF 27/57 reads (47%) | called by muse, mutect2, varscan2
- ETV3 | c.*1385G>T | 3'UTR (SNP) | VAF 12/74 reads (16%) | called by muse, mutect2, varscan2
- EVI5L | c.1200+981C>G | Intron (SNP) | VAF 4/84 reads (5%) | called by muse, mutect2
- EXOC5 | c.*3068G>C | 3'UTR (SNP) | VAF 17/26 reads (65%) | called by muse, mutect2, varscan2
- F11R | c.*1109G>A | 3'UTR (SNP) | VAF 62/127 reads (49%) | called by muse, mutect2, varscan2
- FAHD2B | chr2:97082229 C>G | 3'Flank (SNP) | VAF 13/27 reads (48%) | called by muse, mutect2, varscan2
- FAM171B | c.-93G>C | 5'UTR (SNP) | VAF 3/46 reads (7%) | called by muse, mutect2
- FCGR2C | c.*121C>A | 3'UTR (SNP) | VAF 36/316 reads (11%) | called by muse, mutect2, varscan2
- FEM1C | c.*1377C>G | 3'UTR (SNP) | VAF 25/46 reads (54%) | called by muse, mutect2, varscan2
- FKBP1C | c.*1126G>A | 3'UTR (SNP) | VAF 20/55 reads (36%) | called by muse, mutect2
- FOSL2 | c.-828G>C | 5'UTR (SNP) | VAF 26/114 reads (23%) | called by muse, mutect2, varscan2
- GABRA2 | c.1059+948C>T | Intron (SNP) | VAF 9/63 reads (14%) | called by muse, mutect2, varscan2
- GAS8 | c.*1465G>A | 3'UTR (SNP) | VAF 3/30 reads (10%) | called by muse, mutect2
- GFRA1 | c.*917G>A | 3'UTR (SNP) | VAF 15/46 reads (33%) | catalogued as rs1393494909; called by muse, mutect2, varscan2
- GLCCI1 | c.-545C>T | 5'UTR (SNP) | VAF 11/54 reads (20%) | called by muse, mutect2, varscan2
- GLIS1 | c.*274G>C | 3'UTR (SNP) | VAF 13/89 reads (15%) | catalogued as rs1004415670; called by muse, mutect2, varscan2
- GLRA2 | c.*466A>C | 3'UTR (SNP) | VAF 17/29 reads (59%) | catalogued as rs1016638320; called by muse, mutect2, varscan2
- GPR155 | c.*68G>A | 3'UTR (SNP) | VAF 7/42 reads (17%) | called by muse, mutect2, varscan2
- GPRIN3 | c.*918G>C | 3'UTR (SNP) | VAF 42/95 reads (44%) | called by muse, mutect2, varscan2
- HDAC2 | c.*4655C>T | 3'UTR (SNP) | VAF 17/66 reads (26%) | called by muse, mutect2, varscan2
- HEPACAM | c.*1065T>A | 3'UTR (SNP) | VAF 17/32 reads (53%) | called by muse, mutect2, varscan2
- HIPK2 | c.*8091G>A | 3'UTR (SNP) | VAF 18/61 reads (30%) | called by muse, mutect2, varscan2
- HJURP | c.*479G>C | 3'UTR (SNP) | VAF 6/10 reads (60%) | catalogued as rs1161784874; called by muse, mutect2, varscan2
- HK2 | c.-307C>G | 5'UTR (SNP) | VAF 6/21 reads (29%) | called by muse, mutect2
- HOXB3 | chr17:48545538 G>A | 3'Flank (SNP) | VAF 22/45 reads (49%) | called by muse, mutect2, varscan2
- HS3ST5 | c.*1109C>T | 3'UTR (SNP) | VAF 5/63 reads (8%) | called by muse, mutect2
- HSD17B13 | c.*433G>C | 3'UTR (SNP) | VAF 35/84 reads (42%) | called by muse, mutect2, varscan2
- HSP90AB3P | n.1034G>A | RNA (SNP) | VAF 8/164 reads (5%) | called by muse, mutect2
- IL2RB | c.*663C>T | 3'UTR (SNP) | VAF 6/104 reads (6%) | called by muse, mutect2
- INTS4 | c.2228+797T>A | Intron (SNP) | VAF 51/102 reads (50%) | called by muse, mutect2, varscan2
- IQCH | c.387+24898G>T | Intron (SNP) | VAF 11/53 reads (21%) | called by muse, mutect2
- IQCH | c.387+24900A>C | Intron (SNP) | VAF 11/54 reads (20%) | called by muse, mutect2
- ISG20L2 | c.*1315T>G | 3'UTR (SNP) | VAF 23/56 reads (41%) | called by muse, mutect2, varscan2
- ISX | c.*1309G>A | 3'UTR (SNP) | VAF 18/110 reads (16%) | called by muse, varscan2
- ITGB5 | c.*1287G>A | 3'UTR (SNP) | VAF 8/55 reads (15%) | called by muse, mutect2, varscan2
- ITPR3 | c.*528C>T | 3'UTR (SNP) | VAF 19/77 reads (25%) | called by muse, mutect2, varscan2
- KCND1 | c.*470C>T | 3'UTR (SNP) | VAF 17/55 reads (31%) | called by muse, mutect2, varscan2
- KCTD10 | c.474+29C>G | Intron (SNP) | VAF 29/174 reads (17%) | called by muse, mutect2, varscan2
- KIAA1958 | c.*246A>C | 3'UTR (SNP) | VAF 12/92 reads (13%) | called by muse, mutect2, varscan2
- KIF13A | chr6:17760742 G>T | 3'Flank (SNP) | VAF 5/33 reads (15%) | called by muse, mutect2, varscan2
- KMT5B | c.*1684G>A | 3'UTR (SNP) | VAF 8/133 reads (6%) | called by muse, mutect2
- LDOC1 | c.-57G>A | 5'UTR (SNP) | VAF 14/41 reads (34%) | called by muse, mutect2, varscan2
- LINC01565 | n.465C>T | RNA (SNP) | VAF 6/60 reads (10%) | called by muse, mutect2, varscan2
- LIPJ | c.-94G>A | 5'UTR (SNP) | VAF 40/102 reads (39%) | catalogued as rs1018872102, COSV63303337; called by muse, mutect2, varscan2
- LOXL2 | c.*214C>A | 3'UTR (SNP) | VAF 24/62 reads (39%) | called by muse, mutect2
- LPP | c.*3253G>A | 3'UTR (SNP) | VAF 17/36 reads (47%) | catalogued as rs555317841; called by muse, mutect2, varscan2
- LRP1 | c.841+4295G>A | Intron (SNP) | VAF 10/81 reads (12%) | called by muse, mutect2, varscan2
- LTB | c.162+18G>C | Intron (SNP) | VAF 38/71 reads (54%) | called by muse, mutect2, varscan2
- LTBP1 | c.1034-109C>G | Intron (SNP) | VAF 13/240 reads (5%) | called by muse, mutect2
- LTBP3 | c.2597-79G>C | Intron (SNP) | VAF 6/16 reads (38%) | called by muse, mutect2, varscan2
- LYRM4 | c.*67G>A | 3'UTR (SNP) | VAF 8/73 reads (11%) | called by muse, mutect2
- MAP3K1 | c.*329C>G | 3'UTR (SNP) | VAF 24/45 reads (53%) | called by muse, mutect2, varscan2
- MAT2A | c.*512C>G | 3'UTR (SNP) | VAF 10/182 reads (5%) | called by muse, mutect2
- MCF2L | chr13:113097113 G>A | 3'Flank (SNP) | VAF 26/43 reads (60%) | called by muse, mutect2, varscan2
- MDFIC | c.*930G>A | 3'UTR (SNP) | VAF 34/106 reads (32%) | called by muse, mutect2, varscan2
- MED12L | c.*97C>A | 3'UTR (SNP) | VAF 43/95 reads (45%) | called by muse, mutect2, varscan2
- METAP1D | chr2:171999731 G>C | 5'Flank (SNP) | VAF 6/16 reads (38%) | called by muse, mutect2, varscan2
- MINDY2 | c.*1211G>C | 3'UTR (SNP) | VAF 8/22 reads (36%) | called by muse, mutect2
- MIRLET7A3 | chr22:46112996 C>T | 3'Flank (SNP) | VAF 4/70 reads (6%) | called by muse, mutect2
- MSL3 | c.*692C>T | 3'UTR (SNP) | VAF 55/129 reads (43%) | called by muse, mutect2, varscan2
- MTX1 | chr1:155216793 G>A | 3'Flank (SNP) | VAF 6/44 reads (14%) | called by muse, mutect2
- MUC21 | c.*1537C>G | 3'UTR (SNP) | VAF 5/95 reads (5%) | called by muse, mutect2
- MUCL3 | c.*638C>G | 3'UTR (SNP) | VAF 7/112 reads (6%) | called by muse, mutect2
- MYBBP1A | c.*43G>T | 3'UTR (SNP) | VAF 41/78 reads (53%) | called by muse, mutect2, varscan2
- NAALADL2 | c.*763G>A | 3'UTR (SNP) | VAF 9/74 reads (12%) | called by muse, mutect2, varscan2
- NDUFA5 | c.66+327C>T | Intron (SNP) | VAF 126/219 reads (58%) | catalogued as rs1164054473; called by muse, mutect2, varscan2
- NOC2LP2 | n.622G>A | RNA (SNP) | VAF 45/87 reads (52%) | called by muse, mutect2, varscan2
- NRXN1 | c.832+4229C>T | Intron (SNP) | VAF 6/26 reads (23%) | called by muse, mutect2, varscan2
- NTRK2 | c.1585+9271C>G | Intron (SNP) | VAF 33/74 reads (45%) | called by muse, mutect2, varscan2
- NUP58 | chr13:25301583 G>A | 5'Flank (SNP) | VAF 16/73 reads (22%) | called by muse, mutect2, varscan2
- OLFML1 | c.-222C>T | 5'UTR (SNP) | VAF 12/55 reads (22%) | called by muse, mutect2, varscan2
- PAX4 | c.-67G>T | 5'UTR (SNP) | VAF 30/46 reads (65%) | called by muse, mutect2, varscan2
- PCMT1 | c.*788C>G | 3'UTR (SNP) | VAF 15/64 reads (23%) | called by muse, mutect2, varscan2
- PDGFRA | c.*2801G>T | 3'UTR (SNP) | VAF 5/94 reads (5%) | called by muse, mutect2
- PDHA1 | c.*422_*425del | 3'UTR (DEL) | VAF 35/52 reads (67%) | catalogued as rs919633508; called by pindel, varscan2
- PDLIM5 | c.*2915G>C | 3'UTR (SNP) | VAF 9/41 reads (22%) | called by muse, mutect2
- PDPK1 | c.*281C>G | 3'UTR (SNP) | VAF 101/170 reads (59%) | called by muse, mutect2, varscan2
- PDS5A | c.1770+260G>C | Intron (SNP) | VAF 30/61 reads (49%) | called by muse, mutect2, varscan2
- PDXK | c.*2772G>C | 3'UTR (SNP) | VAF 18/95 reads (19%) | called by muse, mutect2, varscan2
- PDZD4 | c.*546G>A | 3'UTR (SNP) | VAF 18/40 reads (45%) | called by muse, mutect2, varscan2
- PDZRN4 | c.*339G>C | 3'UTR (SNP) | VAF 9/46 reads (20%) | catalogued as COSV54198955; called by muse, mutect2, varscan2
- PEX14 | c.*502A>G | 3'UTR (SNP) | VAF 59/103 reads (57%) | called by muse, mutect2, varscan2
- PEX26 | c.*3044C>T | 3'UTR (SNP) | VAF 22/89 reads (25%) | called by muse, mutect2
- PGM2L1 | c.*3443C>G | 3'UTR (SNP) | VAF 6/45 reads (13%) | called by muse, mutect2, varscan2
- PGR | c.*1316G>C | 3'UTR (SNP) | VAF 47/47 reads (100%) | called by muse, mutect2, varscan2
- PLCB1 | c.-227C>T | 5'UTR (SNP) | VAF 4/12 reads (33%) | called by muse, mutect2
- PLEKHH2 | c.*2361C>T | 3'UTR (SNP) | VAF 5/58 reads (9%) | called by muse, mutect2
- POC1A | c.*562C>G | 3'UTR (SNP) | VAF 20/38 reads (53%) | called by muse, mutect2, varscan2
- PPM1H | c.*3593G>A | 3'UTR (SNP) | VAF 7/45 reads (16%) | called by muse, mutect2, varscan2
- PPP1R12B | c.*1565C>T | 3'UTR (SNP) | VAF 20/74 reads (27%) | called by muse, mutect2, varscan2
- PPP1R9A | c.*446G>C | 3'UTR (SNP) | VAF 26/72 reads (36%) | called by muse, mutect2, varscan2
- PPP2R2D | c.*1745G>T | 3'UTR (SNP) | VAF 14/119 reads (12%) | called by muse, mutect2, varscan2
- PPP4R2 | c.*606C>G | 3'UTR (SNP) | VAF 18/106 reads (17%) | called by muse, varscan2
- PRKAR2B | c.*1327C>G | 3'UTR (SNP) | VAF 8/69 reads (12%) | called by muse, mutect2, varscan2
- PRR14L | c.*3267C>G | 3'UTR (SNP) | VAF 36/72 reads (50%) | called by muse, mutect2, varscan2
- PSEN2 | c.-20-1027C>T | Intron (SNP) | VAF 25/41 reads (61%) | catalogued as rs971649518; called by muse, mutect2, varscan2
- PTER | c.*2191C>G | 3'UTR (SNP) | VAF 10/26 reads (38%) | called by muse, mutect2, varscan2
- PTGER3 | c.1077+3948G>A | Intron (SNP) | VAF 4/88 reads (5%) | called by muse, mutect2
- RAB3IP | c.*4368C>T | 3'UTR (SNP) | VAF 18/43 reads (42%) | called by muse, mutect2, varscan2
- RAG1 | c.*1115G>C | 3'UTR (SNP) | VAF 20/44 reads (45%) | called by muse, varscan2
- RAG1 | c.*1189C>T | 3'UTR (SNP) | VAF 9/47 reads (19%) | called by muse, varscan2
- RDH16 | c.-515G>A | 5'UTR (SNP) | VAF 25/76 reads (33%) | called by muse, mutect2, varscan2
- REC8 | c.1320-15C>G | Intron (SNP) | VAF 40/63 reads (63%) | catalogued as rs749563511; called by muse, mutect2, varscan2
- RFLNB | c.*2782C>T | 3'UTR (SNP) | VAF 5/61 reads (8%) | called by muse, mutect2
- RGS4 | c.*3C>A | 3'UTR (SNP) | VAF 84/181 reads (46%) | catalogued as COSV63357204; called by muse, mutect2, varscan2
- RHBDD1 | c.*2830C>T | 3'UTR (SNP) | VAF 20/69 reads (29%) | called by muse, mutect2, varscan2
- RIC1 | c.-154C>T | 5'UTR (SNP) | VAF 22/45 reads (49%) | catalogued as rs1332349205; called by muse, mutect2, varscan2
- RIN3 | c.44+1409C>G | Intron (SNP) | VAF 12/27 reads (44%) | catalogued as rs1347703423; called by muse, mutect2, varscan2
- RN7SL860P | chr19:22599477 G>A | 5'Flank (SNP) | VAF 14/86 reads (16%) | called by muse, mutect2, varscan2
- RNF10 | c.555-39C>T | Intron (SNP) | VAF 35/86 reads (41%) | called by muse, mutect2, varscan2
- RP2 | c.*1002G>A | 3'UTR (SNP) | VAF 12/57 reads (21%) | called by muse, mutect2, varscan2
- RPL41 | c.*33G>C | 3'UTR (SNP) | VAF 5/50 reads (10%) | called by muse, mutect2
- RUNDC1 | c.498+62C>G | Intron (SNP) | VAF 41/77 reads (53%) | called by muse, mutect2, varscan2
- RXRB | c.*392G>C | 3'UTR (SNP) | VAF 48/115 reads (42%) | called by muse, mutect2, varscan2
- SEC24D | c.*101C>G | 3'UTR (SNP) | VAF 14/72 reads (19%) | called by muse, mutect2, varscan2
- SHANK2 | c.1174+24180C>T | Intron (SNP) | VAF 5/50 reads (10%) | called by muse, mutect2, varscan2
- SHOX2 | chr3:158106090 C>G | 5'Flank (SNP) | VAF 86/160 reads (54%) | called by muse, mutect2, varscan2
- SIGLEC17P | n.869C>G | RNA (SNP) | VAF 5/17 reads (29%) | called by mutect2, varscan2
- SLBP | c.*420C>T | 3'UTR (SNP) | VAF 31/65 reads (48%) | called by muse, mutect2, varscan2
- SLC25A44 | c.*1304C>A | 3'UTR (SNP) | VAF 29/67 reads (43%) | called by muse, mutect2, varscan2
- SLC26A9 | c.125+52C>T | Intron (SNP) | VAF 8/53 reads (15%) | called by muse, mutect2
- SLC2A6 | c.-17C>T | 5'UTR (SNP) | VAF 6/19 reads (32%) | called by muse, mutect2, varscan2
- SLC30A8 | c.*983G>A | 3'UTR (SNP) | VAF 4/60 reads (7%) | called by muse, mutect2
- SLC33A1 | chr3:155854442 C>T | 5'Flank (SNP) | VAF 22/42 reads (52%) | called by muse, mutect2, varscan2
- SLC35B4 | c.*4346C>T | 3'UTR (SNP) | VAF 15/49 reads (31%) | called by muse, mutect2, varscan2
- SLC35E3 | c.-115C>T | 5'UTR (SNP) | VAF 34/65 reads (52%) | called by muse, mutect2, varscan2
- SLC39A8 | c.*3G>C | 3'UTR (SNP) | VAF 5/38 reads (13%) | called by muse, mutect2, varscan2
- SLC6A14 | c.*2244T>G | 3'UTR (SNP) | VAF 26/57 reads (46%) | called by muse, mutect2, varscan2
- SLC8A2 | c.2111-25C>T | Intron (SNP) | VAF 10/152 reads (7%) | called by muse, mutect2
- SLC9B2 | c.713+62C>T | Intron (SNP) | VAF 27/47 reads (57%) | called by muse, mutect2, varscan2
- SMAD3 | c.*1555C>T | 3'UTR (SNP) | VAF 12/76 reads (16%) | called by muse, mutect2, varscan2
- SNORD114-14 | chr14:100969992 T>A | 5'Flank (SNP) | VAF 35/88 reads (40%) | called by muse, mutect2, varscan2
- SNX20 | chr16:50666725 C>A | 3'Flank (SNP) | VAF 6/78 reads (8%) | called by muse, mutect2
- SPA17 | c.*334C>T | 3'UTR (SNP) | VAF 33/74 reads (45%) | called by muse, mutect2, varscan2
- SPHK1 | chr17:76384137 C>A | 5'Flank (SNP) | VAF 35/58 reads (60%) | called by muse, mutect2, varscan2
- SRRM4 | c.*4471G>C | 3'UTR (SNP) | VAF 19/90 reads (21%) | called by muse, mutect2, varscan2
- SRSF6 | c.*1940G>A | 3'UTR (SNP) | VAF 39/77 reads (51%) | called by muse, mutect2, varscan2
- ST3GAL2 | c.-1003-1029G>T | Intron (SNP) | VAF 14/68 reads (21%) | called by muse, mutect2, varscan2
- ST7L | c.205+781G>C | Intron (SNP) | VAF 36/161 reads (22%) | called by muse, mutect2, varscan2
- STIP1 | chr11:64185320 G>A | 5'Flank (SNP) | VAF 12/111 reads (11%) | catalogued as rs753192874; called by muse, mutect2
- STX16 | c.*298C>T | 3'UTR (SNP) | VAF 16/86 reads (19%) | called by muse, mutect2, varscan2
- TAB1 | c.*1347C>G | 3'UTR (SNP) | VAF 9/77 reads (12%) | called by muse, mutect2
- TATDN3 | c.67-37C>T | Intron (SNP) | VAF 21/49 reads (43%) | called by muse, mutect2, varscan2
- TCERG1 | c.*57C>A | 3'UTR (SNP) | VAF 7/150 reads (5%) | catalogued as COSV99694855; called by muse, mutect2
- TENM1 | c.*482A>C | 3'UTR (SNP) | VAF 38/62 reads (61%) | called by muse, mutect2, varscan2
- TENM2 | chr5:168263226 C>T | 3'Flank (SNP) | VAF 34/80 reads (43%) | catalogued as rs1184137586; called by muse, mutect2
- TEX261 | c.*1329T>G | 3'UTR (SNP) | VAF 22/52 reads (42%) | called by muse, mutect2, varscan2
- TLL1 | c.*1978G>C | 3'UTR (SNP) | VAF 28/61 reads (46%) | called by muse, mutect2, varscan2
- TLL2 | c.1049-124C>T | Intron (SNP) | VAF 53/94 reads (56%) | called by muse, mutect2, varscan2
- TM4SF4 | c.-167G>A | 5'UTR (SNP) | VAF 21/105 reads (20%) | called by muse, mutect2, varscan2
- TMEM168 | c.*604G>C | 3'UTR (SNP) | VAF 23/66 reads (35%) | called by muse, mutect2, varscan2
- TMEM97 | c.*337T>G | 3'UTR (SNP) | VAF 36/62 reads (58%) | called by muse, mutect2, varscan2
- TMPRSS11B | c.*126C>T | 3'UTR (SNP) | VAF 6/39 reads (15%) | called by muse, mutect2, varscan2
- TMPRSS2 | c.*1479C>T | 3'UTR (SNP) | VAF 6/126 reads (5%) | called by muse, mutect2
- TPR | chr1:186375261 G>A | 5'Flank (SNP) | VAF 9/116 reads (8%) | catalogued as rs1368618414; called by muse, mutect2
- TRERF1 | c.*925C>G | 3'UTR (SNP) | VAF 10/126 reads (8%) | called by muse, mutect2
- TRIM16 | c.*386C>T | 3'UTR (SNP) | VAF 24/50 reads (48%) | called by muse, mutect2, varscan2
- TRIM44 | c.*93C>G | 3'UTR (SNP) | VAF 90/199 reads (45%) | called by muse, mutect2, varscan2
- TSBP1 | c.-94G>C | 5'UTR (SNP) | VAF 28/179 reads (16%) | catalogued as rs4642518; called by muse, mutect2, varscan2
- TSEN15 | chr1:184051667 T>A | 5'Flank (SNP) | VAF 7/14 reads (50%) | called by muse, mutect2, varscan2
- TSHZ3 | c.*1291C>T | 3'UTR (SNP) | VAF 30/48 reads (63%) | called by muse, mutect2, varscan2
- TSPAN18 | c.*1613G>A | 3'UTR (SNP) | VAF 27/150 reads (18%) | called by muse, mutect2, varscan2
- TTC22 | c.-12G>C | 5'UTR (SNP) | VAF 8/81 reads (10%) | called by muse, mutect2, varscan2
- TUBGCP2 | c.1215-158G>C | Intron (SNP) | VAF 14/99 reads (14%) | called by muse, mutect2, varscan2
- UBC | chr12:124914720 G>C | 5'Flank (SNP) | VAF 7/83 reads (8%) | called by muse, mutect2
- UBE2Z | c.*287A>G | 3'UTR (SNP) | VAF 47/89 reads (53%) | called by muse, mutect2, varscan2
- USP22 | c.*1877G>A | 3'UTR (SNP) | VAF 25/48 reads (52%) | called by muse, mutect2, varscan2
- USP38 | c.-526A>T | 5'UTR (SNP) | VAF 9/63 reads (14%) | called by muse, mutect2, varscan2
- VPS26A | chr10:69123895 G>C | 5'Flank (SNP) | VAF 7/46 reads (15%) | called by muse, mutect2, varscan2
- WNT3A | c.*1203C>T | 3'UTR (SNP) | VAF 35/111 reads (32%) | called by muse, mutect2, varscan2
- WNT7A | c.*152A>G | 3'UTR (SNP) | VAF 50/104 reads (48%) | catalogued as rs1213104586, COSV53201415; called by muse, mutect2, varscan2
- WSB1 | c.-229G>A | 5'UTR (SNP) | VAF 3/41 reads (7%) | called by muse, mutect2
- XIST | n.9330C>T | RNA (SNP) | VAF 10/76 reads (13%) | called by muse, mutect2, varscan2
- XKR6 | c.764+76337T>C | Intron (SNP) | VAF 19/99 reads (19%) | catalogued as rs375800113; called by muse, mutect2, varscan2
- XPO4 | c.*1670T>G | 3'UTR (SNP) | VAF 54/117 reads (46%) | called by muse, mutect2, varscan2
- YWHAEP5 | n.56G>A | RNA (SNP) | VAF 121/224 reads (54%) | called by muse, mutect2, varscan2
- ZC3H14 | c.*1937G>A | 3'UTR (SNP) | VAF 10/45 reads (22%) | catalogued as rs1365800108; called by muse, mutect2, varscan2
- ZCCHC8 | c.672-99C>T | Intron (SNP) | VAF 7/31 reads (23%) | called by muse, varscan2
- ZFP36L1 | c.-27C>G | 5'UTR (SNP) | VAF 4/51 reads (8%) | catalogued as COSV100322377, COSV100323015; called by muse, mutect2
- ZFPM2 | c.*82A>C | 3'UTR (SNP) | VAF 16/46 reads (35%) | called by muse, mutect2, varscan2
- ZFYVE27 | c.*437C>T | 3'UTR (SNP) | VAF 6/59 reads (10%) | called by muse, mutect2, varscan2
- ZHX3 | c.*96C>T | 3'UTR (SNP) | VAF 19/126 reads (15%) | catalogued as rs539718849; called by muse, mutect2, varscan2
- ZNF467 | chr7:149776974 G>A | 5'Flank (SNP) | VAF 20/60 reads (33%) | called by muse, mutect2, varscan2
- ZNF7 | chr8:144847064 G>A | 3'Flank (SNP) | VAF 7/37 reads (19%) | called by muse, mutect2, varscan2
- ZNF720 | c.*1595C>G | 3'UTR (SNP) | VAF 53/136 reads (39%) | called by muse, mutect2, varscan2
- ZNF783 | c.802+4115C>T | Intron (SNP) | VAF 24/58 reads (41%) | called by muse, mutect2, varscan2
- ZNF84 | c.16-16G>A | Intron (SNP) | VAF 31/92 reads (34%) | called by muse, mutect2, varscan2
- ZNF84 | c.16-15A>T | Intron (SNP) | VAF 31/93 reads (33%) | called by muse, mutect2, varscan2
- ZNF844 | c.*1359C>T | 3'UTR (SNP) | VAF 29/52 reads (56%) | called by muse, mutect2, varscan2
- ZNF844 | c.*3255G>C | 3'UTR (SNP) | VAF 10/154 reads (6%) | called by muse, mutect2
- ZSWIM8 | c.-181G>C | 5'UTR (SNP) | VAF 18/93 reads (19%) | catalogued as COSV65708644; called by muse, mutect2, varscan2
